Somatic mutation profile of tumor specimen TCGA-BR-7851-01A (aliquot TCGA-BR-7851-01A-11D-2201-08) from TCGA case TCGA-BR-7851, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 74.2 years (27,091 days).
Specimen TCGA-BR-7851-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57d3f244-ae93-4604-ba8c-d1ae23b7aa22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7851-10A (Blood Derived Normal), aliquot TCGA-BR-7851-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1de6f01b-5c88-49ec-a06c-412d94a6a2ee

The open-access MAF lists 1,625 somatic variants for this specimen: 1,208 protein-altering or splice-affecting, 393 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 818, Silent 393, Frame Shift Del 248, Nonsense Mutation 52, Frame Shift Ins 48, Splice Site 17, In Frame Del 11, Intron 10, Splice Region 9, 3'UTR 4, RNA 4, Nonstop Mutation 3.

Variants (750 of 1,625; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.3309dup p.D1104Rfs*2 | Frame Shift Ins (INS) | VAF 18/83 reads (22%) | catalogued as rs772267579; ClinVar: pathogenic; called by mutect2, varscan2
- ARID1A | c.4381C>T p.R1461* | Nonsense Mutation (SNP) | VAF 33/87 reads (38%) | hotspot (GDC flag); catalogued as COSV61376088; called by muse, mutect2, varscan2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BMPR2 | c.893G>A p.W298* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as rs1085307271, BM1454431, COSV65810748; ClinVar: pathogenic; called by muse, varscan2
- BRCA1 | c.1016del p.K339Rfs*2 | Frame Shift Del (DEL) | VAF 41/168 reads (24%) | catalogued as rs80357569, CD951606; ClinVar: pathogenic; called by mutect2, varscan2
- CHD2 | c.3734del p.K1245Nfs*4 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | catalogued as rs752940775; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.832C>T p.R278* (on ENST00000281708 / NM_001349798.2; = p.R198* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | hotspot (GDC flag); catalogued as COSV55891638; called by muse, mutect2, varscan2
- FLNB | c.1592dup p.H532Tfs*9 | Frame Shift Ins (INS) | VAF 14/63 reads (22%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- GLB1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780523881, CM056964, COSV56565378; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, varscan2
- MYH2 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1468175087, COSV55435401, COSV55441385; ClinVar: likely pathogenic; called by muse, mutect2
- NPHP3 | c.406del p.T136Rfs*13 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs1379989124, CD1211305; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- OSGEP | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773173317, COSV52832903; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PDZD7 | c.166dup p.R56Pfs*24 | Frame Shift Ins (INS) | VAF 30/116 reads (26%) | catalogued as rs587776894; ClinVar: pathogenic / risk factor; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4705A>G p.N1569D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV52640705; called by muse, mutect2, varscan2
- ABCC10 | c.4279C>T p.R1427C (on ENST00000372530 / NM_001198934.2; = p.R1399C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs375273058; called by muse, mutect2, varscan2
- ABCE1 | c.1141A>T p.N381Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56847739; called by muse, mutect2, varscan2
- ABCF1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as rs757435705, COSV58229691; called by muse, mutect2, varscan2
- ABHD15 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as rs761656909, COSV56195005; called by muse, mutect2, varscan2
- ABLIM1 | c.268C>A p.H90N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.191); catalogued as COSV53309482; called by mutect2, varscan2
- ABRAXAS1 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as rs1300270870, COSV55029469; called by muse, mutect2, varscan2
- AC011455.2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1349392978, COSV55500291; called by muse, mutect2, varscan2
- AC011455.2 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs947932141, COSV55500304; called by muse, mutect2, varscan2
- AC126283.2 | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 30/100 reads (30%) | catalogued as rs768411190, COSV67099110; called by muse, mutect2, varscan2
- AC131160.1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs1171010055, COSV57701155; called by muse, mutect2, varscan2
- AC136428.1 | c.105del p.S36Pfs*2 | Frame Shift Del (DEL) | VAF 24/129 reads (19%) | catalogued as rs763538641; called by mutect2, varscan2
- ACAA1 | c.1105del p.L369Wfs*7 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as COSV100086020; called by mutect2, pindel, varscan2
- ACBD5 | c.1117G>T p.G373* (on ENST00000375888 / NM_001352568.1; = p.G364* on NM_145698.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/307 reads (10%) | catalogued as COSV65520179; called by muse, mutect2, varscan2
- ACIN1 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV52978118; called by muse, mutect2, varscan2
- ACSL1 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs183356632, COSV99860619; called by muse, mutect2, varscan2
- ACTN2 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs566552494, COSV100856979, COSV63976254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTR5 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV54761277; called by muse, mutect2, varscan2
- ACTR8 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as COSV51637333; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 40/70 reads (57%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM21 | c.2051del p.L684Cfs*3 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs546931496; called by mutect2, pindel, varscan2
- ADAM8 | c.1498G>T p.G500W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69864879; called by muse, mutect2, varscan2
- ADAMTS10 | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54356296; called by muse, mutect2, varscan2
- ADAMTS12 | c.3361G>A p.A1121T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV61267494; called by muse, mutect2
- ADCY7 | c.1935G>A p.S645= | Splice Region (SNP) | VAF 11/75 reads (15%) | catalogued as rs556897150, COSV54268205; called by muse, mutect2, varscan2
- ADCY8 | c.1641-1G>T p.X547_splice | Splice Site (SNP) | VAF 25/155 reads (16%) | catalogued as COSV53914004; called by muse, mutect2, varscan2
- ADGRL1 | c.4396G>A p.G1466R (on ENST00000340736 / NM_001008701.3; = p.G1461R on NM_014921.5) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779694675, COSV61565137, COSV61565480; called by mutect2, varscan2
- ADGRL1 | c.782G>A p.R261H (on ENST00000340736 / NM_001008701.3; = p.R256H on NM_014921.5) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.746); catalogued as rs368468552; called by muse, mutect2, varscan2
- ADRA1A | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1173589608, COSV52367680; called by muse, mutect2, varscan2
- AEBP1 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs749154733, COSV56255132; called by muse, mutect2, varscan2
- AFP | c.1043del p.N348Ifs*22 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs779815391; called by mutect2, pindel, varscan2
- AGAP1 | c.386del p.P129Rfs*22 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as COSV58317085; called by mutect2, pindel, varscan2
- AGPAT1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.786); catalogued as rs139093368; called by muse, mutect2, varscan2
- AGTPBP1 | c.2876T>C p.L959S (on ENST00000357081 / NM_001330701.2; = p.L919S on NM_015239.2) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61273538; called by muse, mutect2, varscan2
- AGTPBP1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as rs1299682783, COSV61273551; called by muse, varscan2
- AHCY | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs771494586, COSV54153633; called by muse, varscan2
- AHCY | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.051); catalogued as rs758133308, COSV54153641; called by muse, varscan2
- AHNAK2 | c.6208C>T p.H2070Y | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60920137; called by muse, mutect2
- AHSA1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs147994825, COSV53632455; called by muse, mutect2, varscan2
- AKAP11 | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV50297688; called by muse, mutect2, varscan2
- AKAP6 | c.5165T>C p.L1722P | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV55219700; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- ALDH16A1 | c.1581del p.Y528Mfs*99 | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | catalogued as rs764766875; called by mutect2, pindel, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | catalogued as rs778623472, COSV56735668; called by mutect2, pindel, varscan2
- ALG10 | c.981dup p.V328Cfs*18 | Frame Shift Ins (INS) | VAF 18/53 reads (34%) | catalogued as rs768493124; called by mutect2, pindel, varscan2
- ALG13 | c.383+2T>C p.X128_splice | Splice Site (SNP) | VAF 14/152 reads (9%) | catalogued as COSV52641050; called by muse, mutect2
- ALX1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.132); catalogued as COSV57492978; called by muse, mutect2, varscan2
- AMFR | c.1380+1G>A p.X460_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV51922540; called by muse, mutect2, varscan2
- AMOTL2 | c.818del p.P273Lfs*13 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs1319526303; called by mutect2, pindel, varscan2
- ANAPC10 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs779792432, COSV58739703; called by muse, varscan2
- ANK2 | c.669G>T p.K223N | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52161577; called by muse, mutect2, varscan2
- ANKRD12 | c.1988A>G p.E663G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV100040650; called by muse, varscan2
- ANKRD17 | c.5134C>T p.R1712C | Missense Mutation (SNP) | VAF 57/276 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1403754613, COSV58223155; called by muse, mutect2, varscan2
- ANKRD33 | c.293G>A p.R98Q (on ENST00000340970 / NM_001304459.2; = p.R223Q on NM_182608.4) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as rs764761884, COSV56607125, COSV56607744; called by muse, mutect2, varscan2
- ANO7 | c.445C>T p.R149C (on ENST00000274979; = p.R94C on NM_001001666.4) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs763945681, COSV51467841; called by muse, mutect2, varscan2
- ANXA4 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV67849090; called by muse, mutect2, varscan2
- ANXA8L1 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1331876224; called by muse, mutect2
- AP1B1 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV58019322; called by muse, mutect2, varscan2
- AP2M1 | c.1079G>A p.G360D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53048860; called by muse, mutect2, varscan2
- APOA4 | c.523C>A p.L175M | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV63360663, COSV63360992; called by muse, mutect2, varscan2
- APOB | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as CM148037, COSV51941513; called by muse, mutect2, varscan2
- APOC4 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.079); catalogued as COSV52989951, COSV52990586; called by muse, mutect2
- AQP2 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs763156762, COSV52230820; called by muse, mutect2, varscan2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 28/168 reads (17%) | catalogued as rs3215969; called by mutect2, pindel, varscan2
- AQP8 | c.363del p.M122Cfs*10 | Frame Shift Del (DEL) | VAF 32/138 reads (23%) | catalogued as rs759782104; called by mutect2, pindel, varscan2
- ARAP3 | c.2041G>A p.G681S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1055572281, COSV53351887; called by muse, mutect2, varscan2
- ARFGEF3 | c.3497T>C p.M1166T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.344); catalogued as COSV52461610; called by muse, mutect2
- ARFGEF3 | c.5665G>A p.V1889I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs773962256, COSV52461651; called by muse, mutect2, varscan2
- ARHGAP11A | c.2236G>T p.G746C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.315); catalogued as COSV55707098; called by muse, mutect2, varscan2
- ARHGAP5 | c.2676del p.F892Lfs*9 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs781483073; called by mutect2, pindel, varscan2
- ARHGEF10 | c.466G>T p.G156C (on ENST00000398564; = p.G132C on NM_014629.4) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs751469603, CM158915, COSV50656963, COSV50670812; called by muse, mutect2, varscan2
- ARL4C | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60214298; called by muse, mutect2, varscan2
- ASAP2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs770829193, COSV55634037; called by muse, mutect2, varscan2
- ASCL1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57151979; called by muse, mutect2
- ASH2L | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 114/359 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs767918385, COSV51699794; called by muse, mutect2, varscan2
- ASS1 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs765748014, COSV61689813; called by muse, mutect2, varscan2
- ATF6B | c.855G>T p.Q285H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.804); catalogued as COSV64352122; called by muse, mutect2, varscan2
- ATM | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV53753331; called by mutect2, varscan2
- ATP13A4 | c.2836G>A p.V946I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1301290496, COSV61321793; called by muse, mutect2, varscan2
- ATP1A4 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs143083729; called by muse, mutect2, varscan2
- ATP2A1 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as rs200092983, COSV63921560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B2 | c.3019G>A p.G1007S (on ENST00000352432; = p.G973S on NM_001683.5) | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373150646; called by muse, varscan2
- ATP6V0A2 | c.1521C>A p.S507R | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV57750242; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2044G>A p.G682R | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs766998428, COSV57750255; called by muse, mutect2, varscan2
- ATXN1 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs764254890, COSV55221033, COSV55226393; called by muse, mutect2, varscan2
- AURKB | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs144169786, COSV60245008; called by muse, mutect2, varscan2
- AVIL | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as rs374415947, COSV57682514; called by muse, mutect2, varscan2
- B3GALT6 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55420191; called by muse, mutect2, varscan2
- B3GLCT | c.1237T>C p.C413R | Missense Mutation (SNP) | VAF 86/267 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58456324; called by muse, varscan2
- BAG3 | c.1413G>T p.E471D | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as COSV64842204; called by muse, mutect2, varscan2
- BAIAP3 | c.2947C>T p.R983W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199818225, COSV99136119; called by muse, varscan2
- BANP | c.961C>T p.R321C (on ENST00000286122; = p.R290C on NM_017869.4) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1411104336, COSV53739464; called by muse, mutect2, varscan2
- BCHE | c.223_224del p.Q75Vfs*7 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as rs1276780397; called by pindel, varscan2
- BCL7C | c.617del p.P206Hfs*36 | Frame Shift Del (DEL) | VAF 36/183 reads (20%) | catalogued as rs754078059; called by mutect2, pindel, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 16/30 reads (53%) | catalogued as rs768244116; called by mutect2, pindel
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs752427670; called by mutect2, varscan2
- BECN1 | c.1041G>C p.K347N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59312234; called by muse, mutect2, varscan2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- BHLHE22 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs866854588, COSV58861479; called by muse, mutect2
- BIN2 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.039); catalogued as rs1312405207, COSV99909118; called by muse, mutect2, varscan2
- BIRC6 | c.11866G>A p.A3956T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV70201921; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4895G>A p.R1632H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.15); catalogued as rs188710607, COSV63245652; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP3 | c.1062G>T p.Q354H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51088124; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BNC2 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV66150783; called by muse, mutect2, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as COSV56263190; called by mutect2, pindel, varscan2
- BRAT1 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.464); catalogued as rs750645922, COSV61396025; called by muse, mutect2, varscan2
- BTNL3 | c.1132T>C p.W378R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61565159; called by muse, mutect2, varscan2
- BUB1B | c.2996G>A p.R999Q | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs377612791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C12orf42 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV59385299; called by muse, mutect2, varscan2
- C19orf44 | c.1955_1957del p.E652del | In Frame Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs748079004; called by pindel, varscan2
- C19orf57 | c.1942dup p.L648Pfs*115 (on ENST00000586783 / NM_001345843.1; = p.L617Pfs*115 on NM_024323.5 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 15/58 reads (26%) | catalogued as rs1270763461; called by mutect2, pindel, varscan2
- C1orf109 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as COSV59239357; called by muse, mutect2, varscan2
- C2orf78 | c.2710T>A p.F904I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.663); catalogued as COSV68518216; called by muse, mutect2, varscan2
- C3orf62 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs780386279, COSV57985348; called by muse, mutect2, varscan2
- C4orf50 | c.688T>G p.C230G (on ENST00000324058; = p.C1462G on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60689306; called by muse, mutect2, varscan2
- C9orf43 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55913126; called by muse, mutect2, varscan2
- C9orf50 | c.1057A>T p.T353S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.089); catalogued as COSV65252646; called by muse, mutect2, varscan2
- CABP4 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs771931640, COSV100351399, COSV56887188; called by muse, mutect2, varscan2
- CACNA1B | c.986A>G p.N329S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.11); catalogued as COSV53133573; called by muse, mutect2, varscan2
- CADM4 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55929267, COSV99731474; called by muse, mutect2, varscan2
- CALD1 | c.2022G>T p.K674N (on ENST00000361675 / NM_033138.4; = p.K419N on NM_004342.7) | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62649625; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAP2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1422077419, COSV57733902; called by muse, mutect2, varscan2
- CAPN3 | c.2370G>T p.E790D | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV55518293; called by muse, mutect2, varscan2
- CARD11 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs1225008718, COSV67797853, COSV67798790; called by muse, mutect2, varscan2
- CARD14 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs757622443, COSV60124621; called by muse, mutect2, varscan2
- CARD8 | c.1238C>T p.P413L (on ENST00000651546 / NM_001184900.3; = p.P363L on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV100751315, COSV62874123; called by muse, mutect2, varscan2
- CARMIL3 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs777788779, COSV57727137; called by muse, mutect2, varscan2
- CAV3 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV57479806; called by muse, mutect2, varscan2
- CBFA2T2 | c.1321del p.T441Qfs*5 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as COSV100656585; called by mutect2, pindel, varscan2
- CCDC15 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as rs751080852, COSV61082956; called by muse, mutect2, varscan2
- CCDC65 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV57196304; called by muse, mutect2, varscan2
- CCDC89 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs1227881374, COSV57034397; called by muse, mutect2, varscan2
- CCIN | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs373879432; called by muse, mutect2, varscan2
- CCKAR | c.818A>T p.K273M | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.315); catalogued as COSV55162301; called by muse, varscan2
- CCL16 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs537862229; called by muse, mutect2, varscan2
- CD1D | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as rs1469165638, COSV63809061; called by muse, mutect2, varscan2
- CD248 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768897237, COSV60936932; called by muse, mutect2, varscan2
- CD8A | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs771963865, COSV52158173; called by muse, mutect2, varscan2
- CDC42BPB | c.3880A>G p.I1294V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63475663; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs762194001; called by mutect2, varscan2
- CDC73 | c.306G>A p.A102= | Splice Region (SNP) | VAF 16/54 reads (30%) | catalogued as rs141131532, CD023515; called by muse, mutect2, varscan2
- CDCA3 | c.700G>T p.G234* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV57529258; called by mutect2, varscan2
- CDH8 | c.1912G>A p.V638M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs749935575, COSV54845694; called by muse, mutect2, varscan2
- CDHR1 | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV60563195; called by muse, mutect2, varscan2
- CDK12 | c.1126A>G p.S376G | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1473839774, COSV71001419; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1153C>A p.L385M (on ENST00000357886 / NM_001365728.1; = p.L371M on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59427650; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4598T>C p.L1533P | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62575579; called by muse, mutect2, varscan2
- CEBPZ | c.1428del p.D477Mfs*11 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs763090473; called by mutect2, varscan2
- CELSR3 | c.5151A>G p.A1717= | Splice Region (SNP) | VAF 4/37 reads (11%) | catalogued as COSV50896459; called by muse, mutect2
- CEP128 | c.1238A>G p.E413G | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1376499115, COSV55381566, COSV55392163; called by muse, mutect2, varscan2
- CEP164 | c.2668C>T p.R890C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs772514202, COSV54043162; called by muse, mutect2, varscan2
- CEP164 | c.3271T>G p.L1091V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV54043173; called by muse, mutect2, varscan2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel, varscan2
- CFAP52 | c.1306G>A p.G436S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs752178735, COSV55346311; called by muse, mutect2, varscan2
- CFAP92 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.017); catalogued as rs1325907900, COSV54047943, COSV99414473; called by muse, mutect2, varscan2
- CFHR5 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV56823762; called by muse, mutect2, varscan2
- CFL1 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV57380536; called by muse, mutect2, varscan2
- CFP | c.953G>A p.W318* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV55950621; called by muse, mutect2, varscan2
- CGN | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 31/106 reads (29%) | catalogued as rs376940080; called by muse, mutect2, varscan2
- CHD3 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs771669987, COSV100390630; called by muse, mutect2, varscan2
- CHD5 | c.4474C>T p.R1492W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761795865, COSV52418303; called by muse, mutect2
- CHD9 | c.3001A>G p.R1001G | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54608224; called by muse, mutect2, varscan2
- CHRDL1 | c.1023G>A p.M341I (on ENST00000372045; = p.M347I on NM_145234.4) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54326410; called by muse, mutect2, varscan2
- CILP | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.607); catalogued as rs371987972; called by muse, mutect2, varscan2
- CILP | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56022487, COSV99973955; called by muse, mutect2, varscan2
- CIT | c.3001C>T p.R1001* | Nonsense Mutation (SNP) | VAF 50/135 reads (37%) | catalogued as COSV55862966; called by muse, mutect2, varscan2
- CLASP1 | c.3107G>A p.S1036N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV55328790; called by mutect2, varscan2
- CLBA1 | c.138_140del p.L47del | In Frame Del (DEL) | VAF 23/108 reads (21%) | catalogued as rs1432961068; called by mutect2, pindel, varscan2
- CLCN4 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs750952479, COSV66467119; called by muse, mutect2, varscan2
- CLIP1 | c.3646del p.R1216Efs*6 (on ENST00000620786 / NM_001247997.1; = p.R1205Efs*6 on NM_002956.2) | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs761972338; called by mutect2, pindel, varscan2
- CLIP1 | c.2060C>T p.A687V (on ENST00000620786 / NM_001247997.1; = p.A676V on NM_002956.2) | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV56803994; called by muse, mutect2, varscan2
- CLIP3 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV62112840, COSV62113082; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 34/71 reads (48%) | catalogued as rs369752219; called by mutect2, varscan2
- CLSTN2 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.895); catalogued as rs555082751, COSV71718074, COSV71720623; called by muse, mutect2, varscan2
- CLSTN3 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs759093363, COSV56935437, COSV56937934; called by muse, mutect2
- CMTR2 | c.1757C>T p.S586L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1567504539, COSV57603779; called by muse, mutect2, varscan2
- CMYA5 | c.10418G>A p.S3473N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV71404945, COSV71407067; called by muse, mutect2, varscan2
- CNBD2 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs534729039, COSV62586255; called by muse, mutect2, varscan2
- CNOT1 | c.3566G>A p.R1189H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV55313195; called by muse, mutect2, varscan2
- CNPPD1 | c.980del p.P327Lfs*86 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs1192122894; called by mutect2, pindel, varscan2
- COL11A1 | c.2495G>A p.G832E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62180978; called by muse, mutect2, varscan2
- COL11A1 | c.1635dup p.P546Afs*9 | Frame Shift Ins (INS) | VAF 26/91 reads (29%) | catalogued as rs779795373; called by mutect2, varscan2
- COL11A2 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs747064765, COSV59498730; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL13A1 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.266); catalogued as COSV62571567; called by muse, varscan2
- COL14A1 | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as rs767547791, COSV52859176; called by muse, mutect2, varscan2
- COL16A1 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV54706105; called by muse, mutect2, varscan2
- COL20A1 | c.3567C>T p.G1189= | Splice Region (SNP) | VAF 8/49 reads (16%) | catalogued as rs746683676, COSV58920067; called by muse, mutect2, varscan2
- COL27A1 | c.2688C>G p.D896E | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.997); catalogued as COSV61927896; called by muse, mutect2, varscan2
- COL4A1 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs765386262, COSV65427806, COSV65430121; called by muse, mutect2, varscan2
- COL4A1 | c.359del p.P120Qfs*36 | Frame Shift Del (DEL) | VAF 47/234 reads (20%) | catalogued as rs1566378788, COSV65422277; called by mutect2, pindel, varscan2
- COMP | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.582); catalogued as rs754522846, COSV55875345; called by muse, mutect2, varscan2
- CPA5 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.735); catalogued as COSV62568765; called by muse, mutect2, varscan2
- CPNE8 | c.1024A>G p.M342V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV58846011; called by muse, mutect2, varscan2
- CPSF3 | c.983C>A p.S328Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53010367; called by muse, mutect2, varscan2
- CPT2 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV53759673, COSV99598386; called by muse, mutect2
- CR1 | c.2596T>C p.C866R | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65458486; called by muse, mutect2, varscan2
- CRAMP1 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs747072572, COSV51963513, COSV99246267; called by muse, mutect2, varscan2
- CRB2 | c.2984T>C p.F995S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63504071; called by muse, mutect2, varscan2
- CREBBP | c.5063C>T p.T1688M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781364836, COSV52127565; called by mutect2, varscan2
- CREBBP | c.4556A>G p.Y1519C | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52129386; called by muse, mutect2, varscan2
- CRIM1 | c.2728A>G p.I910V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV54867111; called by muse, mutect2, varscan2
- CRLF3 | c.516del p.F172Lfs*6 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | catalogued as COSV60835176, COSV60835970; called by mutect2, pindel, varscan2
- CROCC | c.5759C>T p.A1920V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as rs902231283, COSV65003875; called by muse, mutect2, varscan2
- CSNK2A1 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs1442904163, COSV53936018; called by muse, mutect2
- CSRNP3 | c.1023G>T p.E341D | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV58780800; called by muse, mutect2, varscan2
- CTCF | c.1348del p.S450Vfs*61 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | catalogued as rs34679888; called by mutect2, pindel
- CTNNBL1 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV63745590; called by muse, mutect2, varscan2
- CTNNBL1 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as rs751223032, COSV63744017; called by muse, mutect2, varscan2
- CTRL | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs746032624, COSV52123563, COSV52123979; called by muse, mutect2, varscan2
- CUL1 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57388461; called by muse, mutect2, varscan2
- CUX2 | c.3892A>G p.I1298V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.025); catalogued as COSV55637722; called by muse, mutect2
- CYP46A1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55894962; called by muse, mutect2, varscan2
- CYTIP | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51634325; called by muse, mutect2, varscan2
- CYYR1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1157180601, COSV54834120; called by muse, mutect2, varscan2
- DAGLB | c.1282G>T p.A428S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV51705129; called by muse, mutect2
- DAO | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57323221; called by muse, mutect2, varscan2
- DAZAP2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs766793667, COSV66313071; called by muse, mutect2, varscan2
- DBNL | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV68881377, COSV68881717; called by muse, mutect2, varscan2
- DCAF8 | c.1585C>T p.R529W | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58784631; called by muse, mutect2, varscan2
- DCDC1 | c.10del p.T4Qfs*18 | Frame Shift Del (DEL) | VAF 25/97 reads (26%) | catalogued as COSV100664438; called by mutect2, pindel, varscan2
- DCHS1 | c.4325C>T p.A1442V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as rs935788980, COSV55038213; called by mutect2, varscan2
- DCLK1 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55194370; called by muse, mutect2, varscan2
- DCTN1 | c.2915G>A p.R972Q | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62620405, COSV62620830; called by muse, mutect2, varscan2
- DDB1 | c.2113G>A p.D705N | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV57103923; called by muse, mutect2, varscan2
- DDO | c.373A>G p.K125E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.57); catalogued as COSV64470275; called by muse, mutect2, varscan2
- DDX11 | c.1826T>C p.V609A | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV52506515; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 29/65 reads (45%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX60L | c.3566T>C p.L1189P | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV52716283; called by muse, mutect2, varscan2
- DENND1B | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as COSV52467695; called by muse, mutect2, varscan2
- DIP2C | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs772128068, COSV55145361; called by mutect2, varscan2
- DISP2 | c.3151C>T p.R1051C | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763352261, COSV51127425; called by muse, mutect2, varscan2
- DLC1 | c.4081G>A p.E1361K (on ENST00000276297 / NM_001348081.2; = p.E924K on NM_006094.5) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs767802518, COSV52312275; called by muse, mutect2, varscan2
- DLG2 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs749744948, COSV54638303; called by muse, mutect2, varscan2
- DMTF1 | c.231A>G p.P77= | Splice Region (SNP) | VAF 23/113 reads (20%) | catalogued as COSV58686558; called by muse, mutect2, varscan2
- DNAH10 | c.11821T>C p.F3941L (on ENST00000409039; = p.F3880L on NM_207437.3) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68996216; called by muse, mutect2, varscan2
- DNAH5 | c.10366G>A p.A3456T | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as COSV54235545; called by muse, mutect2, varscan2
- DNAH6 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.288); catalogued as rs757399618, COSV99404530; called by muse, mutect2, varscan2
- DNAJB13 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs746225940, COSV100334510, COSV60269942; called by muse, mutect2, varscan2
- DNAJC14 | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs762110639, COSV54478756; called by muse, mutect2, varscan2
- DNAJC5G | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs758282251, COSV56080095; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | catalogued as rs782552436; called by mutect2, varscan2
- DOP1A | c.4358T>C p.I1453T | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs1562348658; called by muse, mutect2, varscan2
- DOP1B | c.984dup p.E329* | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | catalogued as rs1414264989; called by mutect2, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 46/157 reads (29%) | catalogued as rs1475611014; called by mutect2, varscan2
- DPYSL5 | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs755806141, COSV56509437; called by muse, mutect2, varscan2
- DRG2 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56728677; called by muse, mutect2, varscan2
- DSC2 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV51866465; called by muse, mutect2, varscan2
- DSCAML1 | c.2105G>A p.G702D (on ENST00000321322; = p.G642D on NM_020693.4) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV58395399; called by muse, mutect2, varscan2
- DSEL | c.3078del p.Q1027Rfs*4 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs762694026; called by mutect2, pindel, varscan2
- DSP | c.7000C>T p.R2334* | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | catalogued as rs369482721, COSV65793674; called by muse, mutect2, varscan2
- DTX1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57498759; called by muse, mutect2, varscan2
- DVL2 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV50036904; called by muse, mutect2, varscan2
- DYNC1H1 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs797045178, COSV64138607; called by muse, mutect2, varscan2
- DYRK2 | c.1250C>T p.T417M (on ENST00000344096 / NM_006482.3; = p.T344M on NM_003583.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs140246773, COSV59846389, COSV59846716; called by muse, mutect2, varscan2
- E2F7 | c.177del p.K59Nfs*29 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | catalogued as rs771114476; called by mutect2, varscan2
- EBF2 | c.551+1G>A p.X184_splice | Splice Site (SNP) | VAF 6/102 reads (6%) | catalogued as COSV68778874; called by muse, mutect2
- ECE1 | c.248G>A p.C83Y | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.707); catalogued as COSV51660529, COSV51666302; called by muse, mutect2
- ECM1 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.114); catalogued as rs201023252; called by muse, mutect2, varscan2
- EFNB3 | c.991dup p.Q331Pfs*20 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | catalogued as rs756422375; called by mutect2, varscan2
- EGFR | c.2810C>T p.P937L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.305); catalogued as COSV51815464; called by muse, mutect2, varscan2
- EIF2AK2 | c.1090A>G p.I364V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51797358; called by muse, mutect2, varscan2
- EIF2B2 | c.386T>G p.L129R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56720702; called by muse, mutect2, varscan2
- EIF2B3 | c.437A>G p.K146R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV64517294, COSV64517787; called by muse, mutect2, varscan2
- EIF3E | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.185); catalogued as rs1446572107, COSV55203981; called by muse, mutect2, varscan2
- EIF3G | c.901T>C p.S301P | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV53453724; called by muse, mutect2, varscan2
- EIF4B | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs764677800, COSV50404164; called by muse, mutect2, varscan2
- EIF4E1B | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV53780840; called by muse, mutect2, varscan2
- EIF4G1 | c.4499A>G p.D1500G (on ENST00000346169 / NM_198241.3; = p.D1305G on NM_004953.5) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59991992; called by muse, mutect2, varscan2
- EIF4G2 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV60598010; called by muse, mutect2, varscan2
- EIF5A2 | c.204del p.K68Nfs*24 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | catalogued as rs1366837041; called by mutect2, pindel, varscan2
- EIF5AL1 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV73123091; called by muse, mutect2, varscan2
- EIPR1 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1219838910, COSV66130954; called by muse, mutect2, varscan2
- ELAVL3 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs370390792, COSV63645287; called by muse, mutect2, varscan2
- ELOA2 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as rs151198704; called by muse, mutect2, varscan2
- ELP3 | c.370A>G p.T124A | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); catalogued as COSV56459993; called by muse, mutect2, varscan2
- EML3 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1378881358, COSV53883137; called by muse, mutect2, varscan2
- ENAM | c.3333C>G p.D1111E | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); catalogued as COSV68536354; called by muse, mutect2, varscan2
- ENKD1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775312149, COSV54666960; called by muse, mutect2, varscan2
- EPG5 | c.4810-2A>G p.X1604_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99956401; called by muse, varscan2
- EPHA5 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.827); catalogued as COSV56642251; called by muse, mutect2
- EPHB3 | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.35); catalogued as COSV57807168; called by muse, varscan2
- ERG | c.1316C>T p.A439V (on ENST00000398919 / NM_001243428.1; = p.A415V on NM_004449.4) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV55734779; called by muse, mutect2, varscan2
- ESS2 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.594); catalogued as rs889267913, COSV52817475; called by muse, mutect2, varscan2
- EVPL | c.6048G>T p.E2016D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV56912844; called by muse, mutect2, varscan2
- EVX2 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57963965; called by muse, mutect2
- EXOC2 | c.2354A>T p.D785V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV57867945; called by muse, mutect2, varscan2
- EXOC3L4 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV66295699; called by muse, mutect2, varscan2
- EZH1 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV52851824; called by muse, mutect2, varscan2
- EZHIP | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as COSV100539446; called by muse, mutect2, varscan2
- F10 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.642); catalogued as rs867593753, COSV65021005; called by muse, mutect2, varscan2
- FAHD2B | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773944783, COSV99737895; called by mutect2, varscan2
- FAM126B | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs80095445, COSV53773508, COSV53773958; called by muse, mutect2, varscan2
- FAM193A | c.1077A>T p.E359D | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV61195944; called by muse, mutect2, varscan2
- FAM207A | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs1290534880, COSV52420977; called by muse, mutect2
- FAM47C | c.1787del p.P596Rfs*229 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as COSV63724780; called by pindel, varscan2
- FAM83G | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs751321977, COSV58759629; called by muse, mutect2, varscan2
- FANCL | c.461T>C p.L154S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52075648; called by muse, mutect2, varscan2
- FASTKD5 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541661773, COSV53907017; called by muse, mutect2, varscan2
- FAT1 | c.13360G>A p.E4454K | Missense Mutation (SNP) | VAF 116/384 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs367799188; called by muse, mutect2, varscan2
- FAT1 | c.11453G>A p.C3818Y | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV101499226, COSV71674852; called by muse, mutect2, varscan2
- FAT3 | c.7504G>A p.V2502I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.268); catalogued as rs757504785, COSV53071433, COSV53099482; called by muse, mutect2, varscan2
- FAT4 | c.6505A>G p.T2169A | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV58693266; called by muse, mutect2, varscan2
- FBXL7 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as rs376437263, COSV61644450; called by muse, mutect2, varscan2
- FBXO38 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); catalogued as COSV57029053; called by muse, mutect2, varscan2
- FBXO41 | c.2348A>C p.Q783P | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV54586304; called by mutect2, varscan2
- FBXW11 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV51608765; called by muse, mutect2
- FBXW12 | c.505del p.T169Lfs*36 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs767006036; called by mutect2, pindel, varscan2
- FBXW4 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1339805734, COSV100489605, COSV58708549; called by muse, mutect2, varscan2
- FBXW7 | c.1876G>A p.A626T (on ENST00000281708 / NM_001349798.2; = p.A546T on NM_018315.5) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55920687, COSV55929339; called by muse, mutect2, varscan2
- FBXW9 | c.1012C>T p.R338W (on ENST00000587955; = p.R318W on NM_032301.3) | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1174224449, COSV66710084; called by muse, mutect2, varscan2
- FCHO1 | c.1004-1C>T p.X335_splice | Splice Site (SNP) | VAF 18/48 reads (38%) | catalogued as rs772008992, COSV53183307; called by muse, mutect2, varscan2
- FCN2 | c.770G>T p.C257F | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52477582; called by muse, mutect2, varscan2
- FCSK | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as rs752659322, COSV55369694; called by muse, mutect2, varscan2
- FER1L5 | c.5642C>T p.P1881L (on ENST00000623019; = p.P1845L on NM_001293083.2) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747589156, COSV53842530; called by mutect2, varscan2
- FGD1 | c.2470A>G p.I824V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as COSV64309045; called by muse, mutect2, varscan2
- FHDC1 | c.2577_2579del p.V860del | In Frame Del (DEL) | VAF 36/171 reads (21%) | catalogued as rs779895444; called by pindel, varscan2
- FIBP | c.998C>T p.A333V (on ENST00000338369 / NM_198897.2; = p.A326V on NM_004214.5) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.102); catalogued as rs1264366915, COSV57172700; called by muse, mutect2, varscan2
- FIP1L1 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV60997879; called by mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | catalogued as rs752076602; called by mutect2, pindel, varscan2
- FLNB | c.2660C>T p.P887L | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as rs753985242, COSV55884411; called by muse, mutect2, varscan2
- FLNC | c.2491G>A p.V831I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs746478952, CM1512354, COSV57958470; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT4 | c.893A>G p.H298R | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1224066555, COSV56113164; called by muse, mutect2, varscan2
- FMNL2 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV56498148; called by muse, mutect2, varscan2
- FNDC11 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs914978705, COSV64443041; called by muse, mutect2, varscan2
- FNDC4 | c.30del p.S11Afs*17 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs771665646, COSV99253963; called by mutect2, varscan2
- FNTA | c.1134G>T p.Q378H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV56490465; called by muse, mutect2, varscan2
- FOXB1 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.581); catalogued as COSV68526143; called by muse, mutect2, varscan2
- FOXG1 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57397801; called by muse, mutect2, varscan2
- FOXK1 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs766885716, COSV61065181; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 39/76 reads (51%) | catalogued as rs760347049; called by mutect2, pindel, varscan2
- FREM1 | c.4369C>T p.Q1457* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV66525878; called by muse, mutect2, varscan2
- FSIP2 | c.17675C>A p.P5892H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV100553773; called by muse, mutect2, varscan2
- FST | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV56816102; called by muse, mutect2, varscan2
- FSTL5 | c.2081C>T p.T694M | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs367671709, COSV60197692; called by muse, mutect2, varscan2
- FTSJ3 | c.2203A>G p.N735D | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV63790530; called by muse, mutect2, varscan2
- FUT6 | c.752A>G p.H251R | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV99744214; called by muse, mutect2, varscan2
- FZD10 | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361067903, COSV57474313, COSV57475915; called by muse, mutect2, varscan2
- FZD7 | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53810212; called by muse, mutect2, varscan2
- FZD8 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV65968057; called by muse, mutect2, varscan2
- GABRQ | c.1469G>T p.G490V | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV64782649, COSV64783704; called by muse, mutect2, varscan2
- GAL3ST1 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 24/98 reads (24%) | catalogued as COSV58892961; called by muse, mutect2, varscan2
- GALNT2 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376128700; called by muse, mutect2, varscan2
- GALNTL6 | c.875T>A p.I292N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72491773; called by muse, mutect2, varscan2
- GALR2 | c.1033A>G p.M345V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57163384; called by muse, mutect2, varscan2
- GBF1 | c.1717A>G p.T573A (on ENST00000369983 / NM_001377137.1; = p.T572A on NM_004193.3) | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV64146359; called by muse, mutect2
- GCN1 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.022); catalogued as rs891716538, COSV56110151; called by muse, mutect2, varscan2
- GDPD4 | c.1367T>C p.L456P | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60020439; called by muse, mutect2, varscan2
- GEN1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV58057321; called by muse, mutect2, varscan2
- GGA2 | c.1685C>A p.P562H | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV59169132, COSV59170987; called by muse, mutect2, varscan2
- GLE1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs200000562; called by muse, mutect2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 51/164 reads (31%) | catalogued as rs759448855, COSV99954330; called by mutect2, varscan2
- GLI2 | c.1924G>A p.G642R (on ENST00000361492 / NM_001374353.1; = p.G659R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs777362312, COSV100084603, COSV58045239; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GMPPA | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.071); catalogued as rs1323644316, COSV100354408, COSV58007484; called by muse, mutect2, varscan2
- GNG11 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV50350388; called by muse, mutect2
- GNPTAB | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs779983477, COSV54778636; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs370114090; called by mutect2, varscan2
- GP5 | c.374A>G p.E125G | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55462734; called by muse, mutect2, varscan2
- GPC5 | c.935T>C p.I312T | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs202020898; called by muse, mutect2, varscan2
- GPC6 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV65518280; called by muse, mutect2, varscan2
- GPR12 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1245945449, COSV67344549; called by muse, mutect2, varscan2
- GPR50 | c.1373T>C p.V458A | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); catalogued as COSV54440370; called by muse, mutect2
- GPR52 | c.944T>C p.V315A | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV52305917; called by muse, mutect2, varscan2
- GPR6 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483563700, COSV51572627; called by muse, mutect2, varscan2
- GPSM2 | c.1663_1664del p.Q555Efs*6 | Frame Shift Del (DEL) | VAF 14/97 reads (14%) | catalogued as rs1452282186; called by pindel, varscan2
- GPSM3 | c.396del p.Q133Kfs*8 | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | catalogued as rs752813848; called by mutect2, pindel, varscan2
- GPX7 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); catalogued as rs763735633, COSV63652697; called by muse, mutect2, varscan2
- GRAMD2A | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59034157; called by muse, mutect2, varscan2
- GRAMD4 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1294703839, COSV63031028; called by muse, mutect2, varscan2
- GRIA2 | c.2630G>A p.G877D | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1168734640, COSV52395784; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK4 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as rs918517798, COSV70803920; called by muse, mutect2, varscan2
- GRIP1 | c.3362C>T p.T1121I (on ENST00000359742 / NM_001379345.1; = p.T1069I on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV54017340; called by muse, mutect2
- GRM3 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64474562; called by muse, mutect2, varscan2
- GRM4 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as rs776838103, COSV65210309; called by muse, mutect2, varscan2
- GRM5 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769970485, COSV59609310, COSV59624499; called by muse, mutect2, varscan2
- GTF2IRD2 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1422871321; called by muse, mutect2
- GTF3C5 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs181363313; called by muse, mutect2, varscan2
- HABP4 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs764723268, COSV64514963; called by muse, mutect2, varscan2
- HAPLN4 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.031); catalogued as rs751565044, COSV52270245; called by muse, mutect2, varscan2
- HARS1 | c.1255_1257del p.K419del | In Frame Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs779289896; called by pindel, varscan2
- HCN3 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs201556891, COSV64233288; called by muse, mutect2, varscan2
- HCN4 | c.1658A>G p.D553G | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV56084850; called by muse, mutect2, varscan2
- HDC | c.1598C>A p.P533H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV51073183; called by muse, mutect2, varscan2
- HDC | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772945540, COSV51069711; called by muse, mutect2, varscan2
- HDC | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs758334668, COSV51073290, COSV51083952; called by muse, mutect2, varscan2
- HEATR1 | c.2803C>T p.R935C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237006144, COSV63981844; called by muse, mutect2, varscan2
- HECW1 | c.3830G>A p.R1277Q | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs150833111, COSV67833322; called by muse, mutect2, varscan2
- HECW1 | c.4304del p.N1435Tfs*10 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as COSV67828575; called by mutect2, pindel, varscan2
- HELB | c.1612G>T p.A538S | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56074477; called by muse, mutect2, varscan2
- HENMT1 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs747321970, COSV64230372, COSV64230455; called by muse, mutect2, varscan2
- HEPACAM2 | c.941T>C p.V314A (on ENST00000394468 / NM_001039372.4; = p.V302A on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV59061501; called by muse, mutect2, varscan2
- HEXIM1 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60176782, COSV60177236; called by muse, mutect2, varscan2
- HIF3A | c.988C>A p.Q330K (on ENST00000377670 / NM_152795.4; = p.Q261K on NM_022462.4) | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as COSV52200383; called by muse, mutect2, varscan2
- HIF3A | c.1625G>A p.R542H (on ENST00000377670 / NM_152795.4; = p.R473H on NM_022462.4) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs373457121; called by muse, mutect2, varscan2
- HIP1R | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV53442682, COSV53443801; called by muse, mutect2, varscan2
- HIVEP3 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as rs753023139, COSV56018040; called by muse, mutect2, varscan2
- HIVEP3 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV56018047; called by muse, mutect2, varscan2
- HKDC1 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as rs374002325; called by muse, mutect2, varscan2
- HKDC1 | c.2093del p.G698Vfs*20 | Frame Shift Del (DEL) | VAF 21/102 reads (21%) | catalogued as rs771959819; called by mutect2, pindel, varscan2
- HLTF | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs897246384, COSV59501877; called by muse, mutect2, varscan2
- HMMR | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.286); catalogued as rs759515223, COSV62374840; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs761272507; called by mutect2, varscan2
- HNF4A | c.1138A>G p.S380G | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV57385059; called by muse, mutect2, varscan2
- HPSE | c.890A>G p.H297R | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1329045672, COSV60987458; called by muse, mutect2, varscan2
- HS3ST3B1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.085); catalogued as COSV62906804; called by muse, mutect2, varscan2
- HS3ST4 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767787078, COSV58805742; called by muse, mutect2, varscan2
- HS6ST3 | c.1120T>C p.S374P | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.879); catalogued as COSV65012637; called by muse, mutect2, varscan2
- HSCB | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.213); catalogued as COSV53261930; called by muse, mutect2, varscan2
- HSD17B11 | c.476T>C p.M159T | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64154722; called by muse, mutect2
- HSPA12A | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375628817, COSV65020914; called by muse, mutect2, varscan2
- HSPA12B | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.125); catalogued as COSV54767718; called by muse, mutect2, varscan2
- HSPG2 | c.11491G>A p.V3831I | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756266826, COSV65933239; called by muse, mutect2, varscan2
- HSPH1 | c.1731del p.V578Lfs*12 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs750959278, COSV60712362; called by mutect2, varscan2
- HTR5A | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as COSV55284581; called by muse, mutect2, varscan2
- HTR5A | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs780790670, COSV55282302, COSV55284114; called by muse, mutect2, varscan2
- HTR7 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs768133205, COSV53285537; called by muse, mutect2, varscan2
- HYAL3 | c.1125G>A p.M375I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV60187426; called by muse, mutect2, varscan2
- IFNA13 | c.571T>C p.*191Qext*? | Nonstop Mutation (SNP) | VAF 43/159 reads (27%) | catalogued as COSV71924525; called by muse, mutect2, varscan2
- IFT140 | c.633C>T p.D211= | Splice Region (SNP) | VAF 19/80 reads (24%) | catalogued as rs201319525, COSV68487727; called by muse, mutect2, varscan2
- IGF1R | c.2380C>T p.R794W | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs753047347, COSV51308319; called by muse, mutect2, varscan2
- IGF2 | c.473C>T p.P158L (on ENST00000434045 / NM_001127598.3; = p.P102L on NM_000612.6) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs369122420, COSV56096927; called by muse, mutect2, varscan2
- IGFLR1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV53075578; called by muse, mutect2, varscan2
- IGLV4-60 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as rs371776623, COSV101135181; called by muse, mutect2, varscan2
- IGSF11 | c.1277G>A p.R426Q (on ENST00000393775 / NM_001015887.3; = p.R425Q on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.992); catalogued as rs1489229334, COSV61172438; called by muse, mutect2, varscan2
- IL10 | c.379-1G>A p.X127_splice | Splice Site (SNP) | VAF 4/43 reads (9%) | catalogued as COSV65594395, COSV65594684; called by muse, mutect2
- IL13RA1 | c.1189C>G p.L397V | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.918); catalogued as COSV65424686; called by muse, mutect2, varscan2
- IL27RA | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs372221939; called by muse, mutect2, varscan2
- ILDR2 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV54832528; called by muse, mutect2, varscan2
- INPP5J | c.2620C>T p.R874C (on ENST00000331075 / NM_001284285.2; = p.R506C on NM_001002837.2) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV53213172; called by mutect2, varscan2
- INSC | c.1311+2T>C p.X437_splice | Splice Site (SNP) | VAF 8/16 reads (50%) | catalogued as COSV65411476; called by muse, mutect2, varscan2
- INTS3 | c.1028A>G p.Q343R | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59679064; called by muse, mutect2, varscan2
- IQCN | c.1268T>C p.I423T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV66575299; called by muse, mutect2, varscan2
- IQGAP2 | c.4208A>G p.D1403G | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57176305; called by muse, mutect2
- IQUB | c.1811G>T p.C604F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61240321; called by muse, mutect2, varscan2
- IRAK3 | c.995G>A p.S332N | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs377162551, COSV54166696; called by muse, mutect2, varscan2
- IRF2 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV66928430, COSV66929816; called by muse, mutect2, varscan2
- IRX2 | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57412044; called by muse, mutect2, varscan2
- IRX6 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs371123518; called by muse, mutect2, varscan2
- ITGA7 | c.1507G>A p.V503M (on ENST00000555728; = p.V459M on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1430407616, COSV57697118; called by muse, mutect2, varscan2
- ITGB5 | c.1626G>T p.K542N | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV56150431; called by muse, mutect2, varscan2
- ITIH6 | c.3830G>A p.R1277K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54490766, COSV54490948; called by mutect2, varscan2
- ITPRIPL1 | c.1375C>T p.R459W (on ENST00000439118 / NM_001008949.3; = p.R467W on NM_178495.6) | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs760877350, COSV63153940; called by muse, mutect2, varscan2
- JAK3 | c.3257C>A p.P1086Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71686391; called by muse, mutect2, varscan2
- JCHAIN | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV54659338; called by muse, mutect2, varscan2
- KALRN | c.6946G>A p.D2316N (on ENST00000360013 / NM_001024660.4; = p.D619N on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs775753465, COSV52259278; called by muse, mutect2, varscan2
- KANSL1L | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55993780; called by muse, mutect2, varscan2
- KATNIP | c.2800C>T p.R934W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs376191564; called by muse, mutect2, varscan2
- KCNG1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1488203466, COSV65368826; called by muse, mutect2, varscan2
- KCNH2 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51200379; called by muse, mutect2, varscan2
- KCNH7 | c.84dup p.F29Ifs*22 | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | catalogued as rs765235057; called by mutect2, pindel, varscan2
- KCNJ15 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV60811307; called by muse, mutect2, varscan2
- KCNJ16 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.757); catalogued as rs200564862; called by muse, mutect2, varscan2
- KCNMA1 | c.953T>C p.I318T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54260254; called by muse, mutect2, varscan2
- KCNQ5 | c.1721T>C p.I574T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59667858; called by muse, mutect2, varscan2
- KCNU1 | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs764321461, COSV67757463; called by muse, mutect2, varscan2
- KCNV1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV52087035; called by muse, mutect2, varscan2
- KDM5A | c.2098C>T p.L700F | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV66993840; called by muse, mutect2, varscan2
- KEAP1 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | catalogued as COSV50309183; called by muse, mutect2
- KHDRBS2 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.786); catalogued as COSV55467481, COSV55500128; called by muse, mutect2, varscan2
- KIAA0408 | c.381dup p.S128Ifs*18 | Frame Shift Ins (INS) | VAF 27/66 reads (41%) | catalogued as rs762399944; called by mutect2, varscan2
- KIAA0753 | c.1914del p.K638Nfs*18 | Frame Shift Del (DEL) | VAF 37/160 reads (23%) | catalogued as COSV63817190; called by mutect2, pindel, varscan2
- KIAA1522 | c.586C>T p.R196C (on ENST00000373480 / NM_001198972.2; = p.R255C on NM_020888.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.742); catalogued as rs377305212; called by muse, mutect2
- KIAA1549 | c.848T>A p.L283* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV54318481; called by muse, mutect2
- KIF21A | c.4816G>T p.G1606C (on ENST00000361418 / NM_001378440.1; = p.G1593C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62773879; called by muse, mutect2, varscan2
- KIF2B | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs755676458, COSV52132439; called by muse, mutect2, varscan2
- KLF17 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147552179; called by muse, mutect2, varscan2
- KLK8 | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as COSV51593007; called by muse, mutect2, varscan2
- KRT10 | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 39/121 reads (32%) | catalogued as COSV54088905, COSV54090327, COSV99510056; called by muse, mutect2, varscan2
- KRTAP4-12 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs1181224296, COSV101224242; called by muse, mutect2, varscan2
- KSR2 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1427138393, COSV60383489; called by muse, mutect2, varscan2
- LAMB2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs770390029, COSV59734970; called by muse, mutect2, varscan2
- LARGE2 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs758493715, COSV57656118; called by muse, mutect2, varscan2
- LCAT | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs1478362225, CD952176, COSV50453143; called by muse, mutect2, varscan2
- LCLAT1 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58374781; called by muse, mutect2, varscan2
- LDOC1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV65159399; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 17/38 reads (45%) | catalogued as rs780042765; called by mutect2, varscan2
- LMAN1L | c.359A>G p.H120R | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV59002491; called by muse, mutect2, varscan2
- LMOD1 | c.1267C>A p.H423N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV66173146; called by muse, mutect2, varscan2
- LMTK2 | c.4411T>C p.F1471L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51998728; called by muse, mutect2, varscan2
- LPCAT4 | c.1144-2A>G p.X382_splice | Splice Site (SNP) | VAF 17/53 reads (32%) | catalogued as COSV59217558; called by muse, mutect2, varscan2
- LRFN1 | c.1219G>A p.G407S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs1168390267, COSV50463142; called by muse, mutect2, varscan2
- LRP1 | c.4468dup p.E1490Gfs*6 | Frame Shift Ins (INS) | VAF 20/85 reads (24%) | catalogued as rs139915490; called by mutect2, varscan2
- LRP10 | c.329del p.G110Afs*29 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as COSV100612531; called by mutect2, pindel, varscan2
- LRP1B | c.7379C>T p.T2460I | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.726); catalogued as rs1229323191, COSV67184909; called by muse, mutect2, varscan2
- LRP2 | c.7865A>G p.D2622G | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1174561319, COSV55560140; called by muse, varscan2
- LRP4 | c.5504dup p.L1836Pfs*24 | Frame Shift Ins (INS) | VAF 18/79 reads (23%) | catalogued as rs745628337; called by mutect2, varscan2
- LRP5 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.531); catalogued as COSV53718299; called by muse, mutect2, varscan2
- LRP6 | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53788913; called by muse, mutect2, varscan2
- LRRC14 | c.994A>G p.S332G | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52880461; called by muse, mutect2, varscan2
- LRRC27 | c.1548del p.F516Lfs*22 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs761680254; called by pindel, varscan2
- LRRFIP1 | c.2135A>G p.Q712R (on ENST00000392000 / NM_001137552.2; = p.Q688R on NM_004735.4) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55253280; called by muse, mutect2, varscan2
- LRRIQ1 | c.2179T>A p.C727S | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV67832625, COSV67833244; called by muse, mutect2, varscan2
- LRRK1 | c.2180C>T p.A727V | Missense Mutation (SNP) | VAF 95/272 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs891430665, COSV52617176; called by muse, mutect2, varscan2
- LRRN2 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs778124325, COSV65784175; called by muse, mutect2, varscan2
- LSMEM2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs373555383; called by muse, mutect2, varscan2
- LTA4H | c.793T>A p.S265T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV57383113; called by muse, mutect2, varscan2
- LTBP2 | c.3829G>A p.E1277K | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.869); catalogued as COSV56208420; called by muse, mutect2, varscan2
- LUC7L3 | c.1165del p.S389Vfs*3 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | catalogued as rs1229438198; called by mutect2, pindel, varscan2
- LY75 | c.542A>G p.H181R | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55108150; called by muse, mutect2, varscan2
- LYSMD4 | c.803C>A p.P268Q (on ENST00000409796 / NM_001284417.2; = p.P269Q on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV60386985; called by muse, mutect2, varscan2
- LYST | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs564593588, COSV67709120; called by muse, mutect2, varscan2
- MACF1 | c.15994-1G>T p.X5332_splice (on ENST00000372915; = p.X3265_splice on NM_012090.5) | Splice Site (SNP) | VAF 7/119 reads (6%) | catalogued as COSV57129195; called by muse, mutect2
- MAEA | c.649G>A p.A217T (on ENST00000303400 / NM_001017405.3; = p.A176T on NM_005882.5) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53263296; called by muse, mutect2, varscan2
- MAP10 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV69364043; called by muse, mutect2, varscan2
- MAP3K11 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs754035122, COSV58420494; called by muse, mutect2, varscan2
- MAP3K12 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV57233921; called by muse, mutect2, varscan2
- MARK4 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53465407; called by muse, mutect2, varscan2
- MAST1 | c.4514C>A p.P1505Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as rs144944600; called by muse, mutect2, varscan2
- MCM2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.453); catalogued as rs566433714, COSV54034802; called by muse, mutect2, varscan2
- MCM3AP | c.5337del p.F1779Lfs*5 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as COSV52437287; called by mutect2, pindel, varscan2
- MED1 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs1139822, COSV56123365, COSV56126282; called by muse, mutect2, varscan2
- MED13 | c.1991C>A p.P664H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV67264669; called by muse, mutect2, varscan2
- METTL25 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV50259875; called by muse, mutect2, varscan2
- MFGE8 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 45/121 reads (37%) | catalogued as rs141213799, COSV51555726; called by muse, mutect2, varscan2
- MFSD13A | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1230209377, COSV53268019; called by muse, mutect2, varscan2
- MFSD6 | c.837T>G p.Y279* | Nonsense Mutation (SNP) | VAF 42/152 reads (28%) | catalogued as COSV55623620; called by muse, mutect2, varscan2
- MFSD8 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.798); catalogued as COSV56551710; called by muse, mutect2, varscan2
- MFSD8 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56551718; called by muse, mutect2, varscan2
- MFSD9 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151282750; called by muse, mutect2, varscan2
- MICOS13 | c.150dup p.A51Rfs*32 | Frame Shift Ins (INS) | VAF 21/77 reads (27%) | catalogued as rs751944867; called by mutect2, varscan2
- MID1 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs755985917, COSV58196213; called by muse, mutect2, varscan2
- MITF | c.530C>T p.P177L (on ENST00000448226 / NM_006722.3; = p.P71L on NM_000248.4) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV58830448; called by muse, mutect2, varscan2
- MLLT1 | c.1381del p.Q461Rfs*46 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | catalogued as rs772076449; called by mutect2, varscan2
- MMP10 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV54245345; called by muse, mutect2, varscan2
- MMP11 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.472); catalogued as COSV53156973; called by muse, mutect2, varscan2
- MMP20 | c.130T>C p.Y44H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52776541; called by muse, mutect2, varscan2
- MMP25 | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV60680118; called by muse, mutect2, varscan2
- MMP9 | c.2040G>A p.W680* | Nonsense Mutation (SNP) | VAF 30/103 reads (29%) | catalogued as COSV63434207; called by muse, mutect2, varscan2
- MOCS3 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV54866874; called by muse, mutect2, varscan2
- MORN4 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.054); catalogued as COSV56730190; called by muse, mutect2, varscan2
- MPP7 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.041); catalogued as COSV61734525; called by muse, mutect2
- MR1 | c.689del p.P230Qfs*5 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs1254492579; called by mutect2, varscan2
- MROH2B | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.797); catalogued as rs758302074, COSV68186005; called by mutect2, varscan2
- MS4A1 | c.256T>C p.Y86H | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61942373; called by muse, mutect2, varscan2
- MS4A10 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.39); catalogued as COSV57632996; called by muse, mutect2, varscan2
- MSI1 | c.345del p.L116Cfs*3 | Frame Shift Del (DEL) | VAF 46/206 reads (22%) | catalogued as rs748469666; called by mutect2, pindel, varscan2
- MSX1 | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as COSV66947506; called by muse, mutect2
- MTMR7 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs748552340, COSV99471868; called by muse, mutect2, varscan2
- MTNR1B | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs758044308, COSV57067160; called by muse, mutect2, varscan2
- MTTP | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs137997894, COSV55507329; called by muse, mutect2, varscan2
- MUC16 | c.40610G>T p.R13537M | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV66693914; called by muse, mutect2, varscan2
- MUC17 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 201/661 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60293553; called by muse, mutect2, varscan2
- MUC5B | c.13282G>A p.A4428T | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV71593684; called by muse, mutect2, varscan2
- MUL1 | c.974A>G p.E325G | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV51642236; called by muse, mutect2, varscan2
- MYADM | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.053); catalogued as COSV61239325; called by muse, mutect2, varscan2
- MYCBP2 | c.7049G>A p.R2350H (on ENST00000357337; = p.R2388H on NM_015057.5) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs769751615, COSV62026624; called by muse, mutect2, varscan2
- MYH11 | c.4996G>A p.A1666T | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as COSV100258415, COSV55558616; called by muse, mutect2, varscan2
- MYH13 | c.2360C>T p.T787M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs759635353, COSV52833664; called by muse, mutect2, varscan2
- MYH3 | c.1959+2T>C p.X653_splice | Splice Site (SNP) | VAF 5/11 reads (45%) | catalogued as COSV56866785; called by muse, mutect2, varscan2
- MYH6 | c.5170A>G p.S1724G | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV62452069; called by muse, mutect2, varscan2
- MYH6 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1425571023, COSV62448325; called by muse, mutect2, varscan2
- MYH7 | c.3614A>C p.E1205A | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100805658; called by muse, mutect2, varscan2
- MYH7B | c.5665C>T p.R1889C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200049894, COSV52681492; called by muse, mutect2, varscan2
- MYH8 | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780844078, COSV67965035; called by muse, mutect2, varscan2
- MYH9 | c.4717C>A p.L1573M | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV53388792; called by muse, mutect2, varscan2
- MYO15A | c.4049C>G p.A1350G | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52759732; called by muse, mutect2, varscan2
- MYOM3 | c.4288G>A p.E1430K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.024); catalogued as rs367587493; called by muse, mutect2, varscan2
- MYRF | c.1225G>A p.G409S (on ENST00000278836 / NM_001127392.3; = p.G400S on NM_013279.4) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as rs763445446, COSV53890489; called by muse, mutect2, varscan2
- NAA25 | c.1957C>T p.R653* | Nonsense Mutation (SNP) | VAF 68/215 reads (32%) | catalogued as rs757007450, COSV55705654; called by muse, mutect2, varscan2
- NADK | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV58273862; called by muse, mutect2
- NALCN | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51937372; called by muse, mutect2, varscan2
- NALCN | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51942639, COSV99213054; called by muse, mutect2, varscan2
- NAXD | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1006325282, COSV57285599; called by muse, mutect2, varscan2
- NBEAL2 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.076); catalogued as rs530589418, COSV52760017; called by muse, mutect2, varscan2
- NCAN | c.2170T>C p.S724P | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53053559; called by muse, mutect2, varscan2
- NCAPD3 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101599379, COSV73258482; called by muse, mutect2, varscan2
- NCDN | c.676A>G p.S226G | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as COSV57847322; called by muse, mutect2, varscan2
- NCKAP5 | c.5198G>A p.R1733H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371367810; called by muse, mutect2, varscan2
- NCKAP5L | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); catalogued as rs775235522, COSV60130744; called by muse, mutect2, varscan2
- NCOA3 | c.2321T>G p.I774S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV59070297; called by muse, mutect2, varscan2
- NCOR1 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 44/149 reads (30%) | catalogued as COSV51982020; called by muse, mutect2, varscan2
- NCOR2 | c.2956dup p.R986Pfs*76 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | catalogued as rs746871841; called by mutect2, varscan2
- NDE1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.459); catalogued as COSV61273726; called by muse, mutect2, varscan2
- NDUFA12 | c.168del p.F56Lfs*13 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | catalogued as rs754864900; called by mutect2, pindel, varscan2
- NEFL | c.1132G>A p.V378M | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55337450; called by muse, mutect2, varscan2
- NEIL1 | c.508T>C p.F170L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV51231167; called by muse, varscan2
- NEUROD1 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54549617; called by muse, mutect2, varscan2
- NFASC | c.2461G>A p.G821R (on ENST00000339876 / NM_001378329.1; = p.G817R on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58358603; called by muse, mutect2, varscan2
- NFKBIB | c.1007G>A p.S336N | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV58003986; called by muse, mutect2, varscan2
- NGFR | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as rs574245308, COSV50802804; called by muse, mutect2, varscan2
- NIN | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.041); catalogued as COSV55396170; called by muse, mutect2
- NIPBL | c.5366G>A p.R1789Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80358380, CM042516, COSV56942266, COSV56950421; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NKD1 | c.862dup p.R288Pfs*12 | Frame Shift Ins (INS) | VAF 21/80 reads (26%) | catalogued as rs772439983; called by mutect2, varscan2
- NKTR | c.4129T>C p.Y1377H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV51773106; called by muse, mutect2, varscan2
- NKX2-5 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs1244289450, COSV61299439; called by muse, mutect2, varscan2
- NLGN4Y | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.777); catalogued as COSV59297297; called by muse, mutect2, varscan2
- NLRC5 | c.4294G>T p.E1432* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV52657974; called by muse, mutect2, varscan2
- NLRC5 | c.4948G>A p.G1650R | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755149068, COSV52657984; called by muse, mutect2, varscan2
- NLRP5 | c.3251C>T p.A1084V | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.121); catalogued as rs572932270, COSV66765663; called by muse, mutect2, varscan2
- NOL4 | c.43T>C p.C15R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52351638; called by muse, mutect2, varscan2
- NOLC1 | c.1477_1479del p.K493del | In Frame Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs763821794; called by pindel, varscan2
- NOM1 | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV51979717; called by muse, mutect2, varscan2
- NPR2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs115064396, COSV61312215; called by muse, mutect2, varscan2
- NR0B2 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs746783997, COSV54259892; called by muse, mutect2, varscan2
- NRCAM | c.1825G>A p.D609N (on ENST00000379028 / NM_001371124.1; = p.D603N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs565277285, COSV61040886; called by muse, mutect2, varscan2
- NRDE2 | c.3448C>T p.R1150W | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs78302825; called by muse, mutect2, varscan2
- NRDE2 | c.268del p.R90Gfs*69 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | catalogued as rs1249617548, COSV62963847; called by mutect2, pindel, varscan2
- NRG2 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV56835531; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs776154715; called by mutect2, varscan2
- NSD1 | c.5270G>T p.R1757M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61778689; called by muse, mutect2, varscan2
- NSD2 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56387591; called by muse, mutect2, varscan2
- NSMCE3 | c.846C>A p.Y282* | Nonsense Mutation (SNP) | VAF 28/72 reads (39%) | catalogued as COSV54276885; called by muse, mutect2, varscan2
- NTNG1 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV53977286; called by muse, mutect2, varscan2
- NUP160 | c.3397C>T p.R1133* | Nonsense Mutation (SNP) | VAF 44/142 reads (31%) | catalogued as rs373754603, COSV65854876; called by muse, mutect2, varscan2
- NUP98 | c.3904C>T p.R1302* (on ENST00000359171 / NM_001365126.1; = p.R1285* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 42/142 reads (30%) | catalogued as COSV61434300; called by muse, mutect2, varscan2
- NUSAP1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as rs775051382, COSV52971848; called by muse, mutect2, varscan2
- NXF1 | c.413T>C p.M138T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53674772; called by muse, mutect2, varscan2
- OBSCN | c.12164C>T p.T4055M | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs774528737, COSV52790112; called by muse, mutect2, varscan2
- OBSL1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs779820021, COSV54723153; called by muse, mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | catalogued as CD000269; called by mutect2, pindel, varscan2
- OCA2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.054); catalogued as rs776573914, COSV62349810; called by muse, mutect2, varscan2
- OGA | c.460T>A p.L154M | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63382223; called by muse, mutect2, varscan2
- OPRL1 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs753097004, COSV61092088; called by muse, mutect2, varscan2
- OPRM1 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs201310502, COSV57677791; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 30/115 reads (26%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR10Z1 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 24/91 reads (26%) | catalogued as rs755391413; called by mutect2, varscan2
- OR14K1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV99314942; called by muse, mutect2, varscan2
- OR2A2 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV68871902; called by muse, mutect2, varscan2
- OR2B2 | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as COSV57580070; called by muse, mutect2, varscan2
- OR4D2 | c.161A>G p.Q54R | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101613865, COSV73459801; called by muse, mutect2, varscan2
- OR4P4 | c.315dup p.G106Wfs*14 | Frame Shift Ins (INS) | VAF 20/100 reads (20%) | catalogued as rs748398423; called by mutect2, varscan2
- OR4S1 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60679344; called by muse, mutect2, varscan2
- OR52A5 | c.194del p.L65Wfs*20 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | catalogued as rs762677866, COSV100263457; called by mutect2, pindel, varscan2
- OR5A1 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs140829988, COSV100118475; called by muse, mutect2, varscan2
- OR8H3 | c.602T>A p.I201N | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57909801; called by muse, mutect2, varscan2
- OVCH1 | c.3241A>G p.M1081V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.018); catalogued as COSV58964899; called by muse, mutect2, varscan2
- OXER1 | c.231del p.S78Pfs*64 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as rs753912794; called by mutect2, pindel, varscan2
- P2RY2 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as rs575826893, COSV60776727; called by muse, mutect2, varscan2
- P2RY6 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs757708551, COSV62937130; called by muse, mutect2, varscan2
- PALD1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV54975324; called by muse, mutect2, varscan2
- PALD1 | c.917del p.P306Qfs*52 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | catalogued as COSV99698564; called by pindel, varscan2
- PAPPA2 | c.1229del p.G410Efs*47 | Frame Shift Del (DEL) | VAF 18/141 reads (13%) | catalogued as COSV62772783; called by mutect2, pindel, varscan2
- PAQR6 | c.568G>A p.A190T (on ENST00000292291 / NM_001272108.2; = p.A84T on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs770817016, COSV52745742; called by muse, mutect2, varscan2
- PBRM1 | c.835del p.I279Yfs*4 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs771618422; called by mutect2, pindel, varscan2
- PBX4 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs746893120, COSV52062345; called by muse, mutect2, varscan2
- PCDH17 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64973017; called by muse, mutect2, varscan2
- PCDHA1 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV65375149; called by muse, mutect2, varscan2
- PCDHA13 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56489810; called by muse, mutect2, varscan2
- PCDHA3 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.449); catalogued as rs782723863, COSV65368299; called by muse, varscan2
- PCDHA7 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV65336739; called by muse, mutect2, varscan2
- PCDHAC2 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53841355; called by muse, mutect2, varscan2
- PCDHB12 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs782691165, COSV53396750; called by muse, mutect2, varscan2
- PCDHB12 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as rs139586852, COSV53398145, COSV53399009; called by muse, mutect2, varscan2
- PCDHB13 | c.918del p.K306Nfs*30 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | catalogued as rs782213177; called by mutect2, pindel, varscan2
- PCDHB2 | c.223del p.M75Cfs*14 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as rs782086614; called by mutect2, varscan2
- PCDHB5 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.909); catalogued as COSV50657019; called by muse, mutect2, varscan2
- PCDHB9 | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated, low confidence (0.67); PolyPhen probably damaging (0.975); catalogued as COSV53380749; called by muse, mutect2, varscan2
- PCDHGA6 | c.1021A>G p.N341D | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs762208267, COSV53976555; called by muse, mutect2, varscan2
- PCDHGA9 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.025); catalogued as rs746951310, COSV53976570; called by muse, mutect2, varscan2
- PCED1B | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs148925320; called by muse, mutect2, varscan2
- PCGF2 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs780536842; called by muse, mutect2, varscan2
- PCNX1 | c.6824G>A p.R2275Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs755555770, COSV53096987; called by muse, mutect2, varscan2
- PCSK5 | c.3386A>C p.E1129A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs1457259908, COSV101377235; called by muse, mutect2, varscan2
- PDCD11 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV63934378; called by muse, mutect2, varscan2
- PDE1C | c.1467G>T p.E489D | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV58518366, COSV58526069; called by muse, mutect2, varscan2
- PDE4A | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV61800587; called by muse, mutect2, varscan2
- PDS5A | c.692T>G p.L231R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57827597; called by muse, mutect2, varscan2
- PDZD2 | c.2615A>G p.D872G | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV56862975; called by muse, mutect2
- PDZD4 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557076659, COSV51245826, COSV51250084; called by muse, mutect2, varscan2
- PEX11B | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.35); catalogued as rs150236235; called by muse, mutect2, varscan2
- PEX13 | c.568T>C p.Y190H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV54370575; called by muse, mutect2, varscan2
- PFKP | c.1785del p.L596Sfs*27 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | catalogued as rs747416036; called by mutect2, pindel, varscan2
- PGF | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs764795497, COSV53126039; called by muse, mutect2, varscan2
- PGM3 | c.1102T>C p.Y368H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52284649; called by muse, mutect2, varscan2
- PHETA1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as rs566596246, COSV64058842; called by muse, mutect2, varscan2
- PI4KB | c.962G>A p.R321Q (on ENST00000368873 / NM_001369623.1; = p.R333Q on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs745425649, COSV55019054; called by muse, mutect2, varscan2
- PIK3C2B | c.166T>C p.S56P | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV65803805; called by muse, mutect2, varscan2
- PIK3C2G | c.47A>G p.E16G | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as COSV56815992; called by muse, mutect2, varscan2
- PIK3CG | c.2653G>A p.A885T | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs373006568; called by muse, varscan2
- PKD1 | c.4480C>T p.R1494C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.86); catalogued as rs369254259; called by muse, mutect2, varscan2
- PKNOX2 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV53543958; called by muse, mutect2, varscan2
- PKP1 | c.1690A>G p.T564A | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55822763; called by muse, mutect2, varscan2
- PLA2G2E | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64290294, COSV64290590; called by muse, mutect2, varscan2
- PLBD1 | c.1186G>T p.G396* | Nonsense Mutation (SNP) | VAF 21/98 reads (21%) | catalogued as COSV53694505; called by muse, mutect2, varscan2
- PLCH2 | c.2419G>A p.V807M | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs745626292, COSV53945434; called by muse, mutect2, varscan2
- PMF1 | c.485T>G p.L162R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60771839; called by muse, mutect2, varscan2
- PMS1 | c.2447A>G p.N816S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59717596; called by muse, mutect2, varscan2
- PNMA2 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1563368138, COSV72908558; called by muse, mutect2, varscan2
- PNPLA7 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747626695, COSV53001260; called by muse, mutect2, varscan2
- PODXL | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs375173959; called by muse, mutect2, varscan2
- POLK | c.2299T>C p.Y767H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.195); catalogued as rs1362769001, COSV99605488; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | catalogued as rs745933237; called by mutect2, pindel, varscan2
- POLR2A | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs775983104, COSV59493515; called by muse, mutect2, varscan2
- POLR3A | c.3199G>A p.V1067M | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746308530, COSV64931363; called by muse, mutect2, varscan2
- PPM1F | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54284967; called by muse, mutect2, varscan2
- PPP1CA | c.56-1G>A p.X19_splice | Splice Site (SNP) | VAF 27/111 reads (24%) | catalogued as COSV56703800; called by muse, mutect2, varscan2
- PPP1R10 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs748872079, COSV64739717; called by muse, mutect2, varscan2
- PPP1R12C | c.1110del p.I373Sfs*51 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as COSV54738562; called by mutect2, pindel
- PPP1R12C | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54738368; called by muse, mutect2, varscan2
- PPP1R26 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs150799430; called by muse, mutect2, varscan2
- PPP2R5C | c.855G>T p.V285= | Splice Region (SNP) | VAF 11/53 reads (21%) | catalogued as COSV58273058; called by muse, mutect2, varscan2
- PRB4 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 52/243 reads (21%) | catalogued as rs878938070, COSV54397900; called by muse, varscan2
- PRB4 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 46/442 reads (10%) | catalogued as COSV54397915; called by muse, varscan2
- PRCC | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.702); catalogued as rs1361029108, COSV54857069; called by muse, mutect2
- PRCP | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.5); catalogued as rs750741679, COSV57289736; called by muse, mutect2, varscan2
- PRKD3 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV52214767; called by muse, mutect2
- PRPF3 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.009); catalogued as rs782318341, COSV61394444; called by muse, mutect2, varscan2
- PRPF38B | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64224100; called by muse, mutect2, varscan2
- PRSS21 | c.750G>T p.W250C | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50051684, COSV50052272; called by muse, mutect2
- PSAP | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 9/288 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV56473009; called by muse, mutect2
- PSG8 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs1409400000, COSV100125958; called by muse, mutect2, varscan2
- PSMB9 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62754967; called by muse, mutect2, varscan2
- PSMC1 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54321202; called by muse, mutect2, varscan2
- PTCH1 | c.1202G>T p.R401M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59481208; called by muse, mutect2, varscan2
- PTEN | c.106G>T p.G36* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as rs786204854, CM004280, CM124222, COSV100909550, COSV64289957, COSV64297290; called by muse, varscan2
- PTEN | c.140G>T p.R47M | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100909326, COSV64292806; called by muse, varscan2
- PTK2 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as rs778100779, COSV61788107; called by muse, mutect2, varscan2
- PTPN14 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65285323; called by muse, mutect2
- PTPN23 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as COSV55545776; called by muse, mutect2, varscan2
- PTPN3 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs193920798, COSV52701715; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRE | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs1564948186, COSV54553501, COSV99045550; called by muse, mutect2, varscan2
- PTPRG | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs756672469, COSV55632039; called by muse, mutect2, varscan2
- PTPRJ | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV69253029; called by muse, mutect2, varscan2
- PTPRN | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV55349556; called by muse, mutect2, varscan2
- PTRH2 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs747089911, COSV52249240; called by muse, mutect2, varscan2
- PTX4 | c.1191del p.G398Efs*57 (on ENST00000447419 / NM_001328608.2; = p.G393Efs*57 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs772722517, COSV99560265; called by mutect2, pindel, varscan2
- PYDC1 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs775103425, COSV57251675; called by muse, mutect2, varscan2
- PYGM | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 88/292 reads (30%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as rs764465584, COSV51220488; called by muse, mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs754588466; called by mutect2, varscan2
- R3HDM1 | c.1462A>G p.N488D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV51526921; called by muse, mutect2, varscan2
- R3HDML | c.419A>G p.E140G | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV53836468; called by muse, mutect2, varscan2
- RAP2A | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55355386; called by muse, mutect2
- RARA | c.415C>A p.R139S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as rs1454375439, COSV54193754; called by muse, mutect2, varscan2
- RASA1 | c.2513del p.N838Mfs*4 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as rs1561325048; called by mutect2, pindel, varscan2
- RASAL2 | c.1183+2T>C p.X395_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | catalogued as COSV62716746; called by muse, mutect2, varscan2
- RBFOX1 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs145006582, COSV60945907; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM47 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.293); catalogued as COSV55932552; called by muse, mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as COSV56484832; called by mutect2, varscan2
- RBPJ | c.1244G>T p.W415L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60753260; called by muse, mutect2, varscan2
875 further variants in this file (458 protein-altering or splice-affecting, 393 silent, 24 other) are not listed here.
